CCDI case PBCRSL — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/bf36433f-990a-4412-9775-a6de6613aa4e

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Dysembryoplastic neuroepithelial tumor: ICD-O-3 morphology code: 9413/0; Tissue or organ of origin: Parietal lobe; Age at diagnosis: 12.9 years (4,698 days).

Biospecimens (3 samples)
- Sample 0DYKRG: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DYKS1: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DYKSA: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
